Somatic mutation profile of tumor specimen MP2PRT-PATRYC-TBP1-A (aliquot MP2PRT-PATRYC-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATRYC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,133 days).
Specimen MP2PRT-PATRYC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7ec537a-bc57-4c52-b84f-8050c11f24ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATRYC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATRYC-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb51e14e-de2a-4c3a-8c8a-03a9c2671c27

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 6, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 23/518 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CGN | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 33/704 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs763549292; called by muse, mutect2
- MGAT5 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 125/453 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56097932, COSV99924169; called by muse, mutect2, varscan2
- SBNO1 | c.2246G>A p.S749N (on ENST00000420886; = p.S748N on NM_018183.5) | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as rs754718548; called by muse, mutect2, varscan2
- SETD2 | c.4792C>T p.R1598* | Nonsense Mutation (SNP) | VAF 38/368 reads (10%) | catalogued as COSV57429911; called by muse, mutect2
- DLC1 | c.3590A>G p.N1197S (on ENST00000276297 / NM_001348081.2; = p.N760S on NM_006094.5) | Missense Mutation (SNP) | VAF 26/526 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); called by muse, mutect2
- SH3RF2 | c.38C>G p.P13R | Missense Mutation (SNP) | VAF 108/442 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APOA4 | c.423G>A p.Q141= | Silent (SNP) | VAF 92/774 reads (12%) | called by muse, mutect2, varscan2
- FOXQ1 | c.1182G>A p.L394= | Silent (SNP) | VAF 25/643 reads (4%) | called by muse, mutect2
- KIAA1671 | c.5238C>T p.G1746= | Silent (SNP) | VAF 127/624 reads (20%) | catalogued as rs375792383; called by muse, mutect2, varscan2
- SHROOM3 | c.4248G>A p.T1416= | Silent (SNP) | VAF 65/686 reads (9%) | catalogued as rs539069944; called by muse, mutect2
- SLC4A9 | c.2317C>T p.L773= (on ENST00000507527 / NM_001258428.2; = p.L749= on NM_031467.3) | Silent (SNP) | VAF 125/482 reads (26%) | called by muse, mutect2, varscan2
- TEX13D | c.810G>A p.P270= | Silent (SNP) | VAF 22/372 reads (6%) | catalogued as rs1257340351; called by muse, mutect2
